Somatic mutation profile of tumor specimen TCGA-YL-A8SH-01B (aliquot TCGA-YL-A8SH-01B-11D-A377-08) from TCGA case TCGA-YL-A8SH, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.5 years (25,395 days).
Specimen TCGA-YL-A8SH-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d016bcb-0b5c-4d72-9df1-0b7603767478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8SH-10A (Blood Derived Normal), aliquot TCGA-YL-A8SH-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8508a703-3e84-43eb-a46c-9b28d8c7d03d

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 21, Silent 6, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 24/92 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs1057519964, COSV61653339, COSV61655858; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1243G>C p.G415R (on ENST00000373993 / NM_138932.2; = p.G407R on NM_014576.4) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.296); catalogued as COSV99255708, COSV99256733; called by muse, mutect2, varscan2
- BAZ1A | c.1868A>G p.K623R | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1162371434, COSV100701177; called by muse, mutect2, varscan2
- C6orf89 | c.1025C>A p.T342N (on ENST00000373685; = p.T349N on NM_152734.4) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100769739; called by muse, mutect2, varscan2
- DDX24 | c.1715C>G p.T572S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV100428000; called by muse, mutect2, varscan2
- FBN3 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758594630, COSV54455168; called by muse, mutect2, varscan2
- FUT3 | c.851T>A p.F284Y | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV99744713; called by muse, varscan2
- GOT1L1 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.089); catalogued as COSV100294575; called by muse, mutect2, varscan2
- GYS1 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99620855; called by muse, mutect2, varscan2
- KRTAP4-4 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs201735937, COSV66811162; called by muse, mutect2, varscan2
- LAMB1 | c.479G>T p.W160L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99741106; called by muse, mutect2, varscan2
- LRP12 | c.1382A>G p.N461S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs1451305179, COSV99407939; called by muse, mutect2, varscan2
- LRRTM3 | c.1092T>G p.S364R | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV100791748; called by muse, mutect2, varscan2
- NCOA3 | c.2599A>G p.S867G | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1206632505, COSV100507716, COSV59071365; called by muse, mutect2, varscan2
- NRG2 | c.1493C>G p.S498C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as rs377110446; called by muse, mutect2, varscan2
- PNLIPRP1 | c.325T>A p.C109S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724432; called by muse, mutect2, varscan2
- TBX3 | c.566A>T p.D189V | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99983890; called by muse, mutect2
- TFCP2L1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); catalogued as rs747701705, COSV55288939, COSV99748353; called by muse, mutect2, varscan2
- THOC5 | c.1990G>T p.G664C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803618; called by muse, mutect2
- THTPA | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99846242; called by mutect2, varscan2
- ATM | c.5812del p.Y1938Ifs*2 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- IGKV1-6 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- GOLGA2 | c.795G>A p.T265= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs781462903, COSV70168890; called by muse, mutect2, varscan2
- LRP4 | c.105A>C p.A35= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs766633369, COSV101066680; called by muse, mutect2, varscan2
- MOV10L1 | c.2499C>T p.F833= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs139092160, COSV53168460; called by muse, mutect2, varscan2
- PCDHGA8 | c.438G>A p.A146= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV54013785; called by muse, mutect2, varscan2
- TCF12 | c.438A>G p.L146= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs1257640285, COSV99977931; called by muse, mutect2, varscan2
- URAD | c.42C>T p.F14= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs267603794, COSV60381161; called by muse, mutect2, varscan2
